TCGA case TCGA-06-0155 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fa1f1cfc-9da0-488b-93fe-60aaff99c171

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Dead; Days to death: 318 days.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 61.6 years (22,498 days); Year of diagnosis: 1998; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Mivobulin Isethionate; Treatment intent type: Adjuvant; Days to treatment start: 9 days; Days to treatment end: 52 days; Treatment dose: 400 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 72 days; Days to treatment end: 120 days; Treatment dose: 5,944 cGy; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine; Treatment intent type: Adjuvant; Days to treatment start: 144 days; Days to treatment end: 236 days; Number of cycles: 2; Treatment dose: 80 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine; Treatment intent type: Adjuvant; Days to treatment start: 175 days; Days to treatment end: 205 days; Number of cycles: 2; Prescribed dose: 80; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine Implant; Treatment intent type: Palliative; Days to treatment start: 257 days; Days to treatment end: 257 days; Number of cycles: 1; Treatment dose: 8 Wafer.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 62.3 years (22,754 days); Days to diagnosis: 256 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 257 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for progressive disease.

Follow-up (5 entries)
- Day 256 (post initial treatment): Progression or recurrence: Yes; Days to progression: 256 days.
- Days to follow up: 263 days; Disease response: With Tumor.
- Days to follow up: 318 days; Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Preoperative.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-0155-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.4; Intermediate dimension: 0.8; Shortest dimension: 0.3.
  Slide TCGA-06-0155-01B-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent necrosis: 10; Percent stromal cells: 10.
  Slide TCGA-06-0155-01B-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 95; Percent necrosis: 10; Percent stromal cells: 10.
- Sample TCGA-06-0155-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Pharmaceutical therapy drug name: Bcnu.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: CI980.
- Drug treatment 3: Pharmaceutical therapy drug name: Gliadel Wafer.
- Drug treatment 3, Route of administrations: Route of administration: Other (specify below).
- Drug treatment 4, Route of administrations: Route of administration: PO.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 318 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 318 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 256 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-06-0155-01B-01D-0517-01): tumor purity 0.79, ploidy 2.02, whole-genome doublings 0.
